Somatic mutation profile of tumor specimen 0DOV9R from CCDI case PBCCSA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (308 days).
Specimen 0DOV9R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b9e238c-24b5-47fc-bdb0-f7293e82f4fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84518f6e-881f-404e-a3d9-84eadfe3689a

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 5, 3'UTR 3, Silent 2, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 221/808 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 460/971 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1267952827, COSV62820100; called by muse, mutect2, varscan2
- CHD1L | c.1159+8C>A | Splice Region (SNP) | VAF 24/649 reads (4%) | catalogued as rs370469707; called by muse, mutect2
- CNOT1 | c.4295C>T p.S1432L | Missense Mutation (SNP) | VAF 21/515 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV55315174; called by muse, mutect2
- COL5A2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 85/1066 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754429372, COSV66410611; ClinVar: uncertain significance; called by muse, mutect2
- TRIM6-TRIM34 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 32/738 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1564884621; called by muse, mutect2
- WDR1 | c.1459G>T p.E487* (on ENST00000382452; = p.E347* on NM_005112.5) | Nonsense Mutation (SNP) | VAF 61/303 reads (20%) | catalogued as COSV66723836; called by muse, mutect2, varscan2
- C11orf80 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 306/993 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 33/937 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- DAG1 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 175/605 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GREB1L | c.4387C>A p.H1463N | Missense Mutation (SNP) | VAF 121/522 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- KDM4C | c.2756G>A p.R919K | Missense Mutation (SNP) | VAF 216/589 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- LPO | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NXPH2 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 76/495 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5B2 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 249/961 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIK3C2G | c.2169C>A p.F723L (on ENST00000676171; = p.F682L on NM_004570.5) | Missense Mutation (SNP) | VAF 134/760 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCNN1A | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SORBS2 | c.1109G>T p.S370I | Missense Mutation (SNP) | VAF 233/559 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ANO3 | c.1941C>A p.V647= | Silent (SNP) | VAF 273/1030 reads (27%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 38/1061 reads (4%) | called by muse, mutect2
- AL132655.6 | chr20:58840783 G>A | 5'Flank (SNP) | VAF 119/452 reads (26%) | catalogued as COSV58342276; called by muse, mutect2, varscan2
- CCDC154 | c.1317+60C>A | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- CEACAM3 | c.*16G>T | 3'UTR (SNP) | VAF 72/350 reads (21%) | catalogued as rs782079072; called by muse, mutect2
- CEL | c.*74C>T | 3'UTR (SNP) | VAF 5/104 reads (5%) | catalogued as rs1227970566; called by muse, mutect2
- CNTNAP3 | c.*75C>A | 3'UTR (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- GCSAM | c.99-77G>T | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- TPM1 | c.563+16G>A | Intron (SNP) | VAF 104/288 reads (36%) | catalogued as rs375227208; called by muse, mutect2, varscan2
